Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A819, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A819-01A (Primary Tumor).

Left Adrenal

Date receiving:

Clinical Information

Left necrotic adrenal pheochromocytoma (94 x 56 mm)

Macroscopy:

The surgical specimen weights 171 g after dissection of adipose tissue and contains a tumor of 9 cm with a solid cystic hemorrhagic appearance. The remaining normal adrenal measures 3 cm

Microscopy

A cellular proliferation with large cells and abundant cytoplasm is observed. Cells are polygonal and eosinophilic with occasional intracytoplasmic hyaline globules. Nuclei exhibit some degree of anisokaryosis (mild to moderate), a pale chromatin and prominent nucleoli. On a cutting plane, cellularity is higher with nuclei and cells of smaller size and a certain degree of cellular monotony. Mitoses are rare, a single mitosis is observed for 10 fields with the lens 40. There is no atypical mitosis. These cells are organized in cellular structures or adopt a diffuse architecture arranged in a sparse interstitial tissue but are often highly hemorrhagic with fibrous and cystic reorganizations. There is an abundant hemosiderine deposition. No capsular invasion or vascular invasion was observed. Absence of necrosis.

CONCLUSION

Left adrenal pheochromocytoma, 9 cm long axis.

PASS Score= 6. (Diffuse architecture: 2. High cellularity: 2 Cellular monotony 2)

Translated on

from the original pathological report evaluated on

ICD-O-3
Pheochromocytoma NOS 8700/3
Site Adrenal gland NOS C74.9
JW 10/17/13

Diagnosis	hw 9/24/13	Yes	No

Source: NCI Genomic Data Commons file 968bf4e2-2142-4d0b-bd91-3599f7851937 (TCGA-WB-A819.D345BFD1-4D3B-4281-8A61-65F114FC90BA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).